Somatic mutation profile of tumor specimen TCGA-ZF-AA4U-01A (aliquot TCGA-ZF-AA4U-01A-11D-A38G-08) from TCGA case TCGA-ZF-AA4U, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage III; Tumor grade: High Grade; Age at diagnosis: 70.3 years (25,682 days).
Specimen TCGA-ZF-AA4U-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ed1b125b-31a7-4b11-94e5-bdb29c7ea529.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-ZF-AA4U-10A (Blood Derived Normal), aliquot TCGA-ZF-AA4U-10A-01D-A38J-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d59c89c8-6fd7-4493-9990-438da4fd7c0b

The open-access MAF lists 69 somatic variants for this specimen: 48 protein-altering or splice-affecting, 20 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 42, Silent 20, Nonsense Mutation 5, 3'UTR 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FGFR3 | c.*164G>T | 3'UTR (SNP) | VAF 95/183 reads (52%) | catalogued as rs121913479, CM960656, COSV53390089, COSV99600444; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- FOXP1 | c.1507C>T p.R503* | Nonsense Mutation (SNP) | VAF 25/64 reads (39%) | catalogued as rs797045584, COSV100561722; ClinVar: pathogenic; called by muse, mutect2, varscan2
- IL10RA | c.784C>T p.R262C | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.732); catalogued as rs149491038, CM113378; ClinVar: pathogenic; called by muse, mutect2
- KLHL3 | c.1292G>A p.R431Q | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs199469643, CM120724; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.3010A>G p.M1004V | Missense Mutation (SNP) | VAF 26/66 reads (39%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen benign (0.254); catalogued as COSV55914513; called by muse, mutect2, varscan2
- ADAMTS9 | c.1292C>T p.T431M | Missense Mutation (SNP) | VAF 75/175 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1265031681, COSV55779734; called by muse, mutect2, varscan2
- ATP10A | c.2426G>T p.R809L | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs776829827, COSV63516508, COSV63516647, COSV63518546; called by muse, mutect2, varscan2
- ATXN2L | c.1663C>A p.Q555K | Missense Mutation (SNP) | VAF 48/140 reads (34%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.9); catalogued as COSV57365304, COSV57368995; called by muse, mutect2
- C1orf127 | c.1823G>A p.R608H | Missense Mutation (SNP) | VAF 31/70 reads (44%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs147303952; called by muse, mutect2, varscan2
- C8orf76 | c.335C>T p.A112V | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs754518679, COSV52690146; called by muse, mutect2, varscan2
- CDH18 | c.1535C>T p.T512I | Missense Mutation (SNP) | VAF 29/67 reads (43%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as COSV56917389; called by muse, mutect2, varscan2
- CHGA | c.622C>T p.Q208* | Nonsense Mutation (SNP) | VAF 4/12 reads (33%) | catalogued as COSV53662969; called by muse, mutect2, varscan2
- CNTNAP2 | c.1139C>T p.A380V | Missense Mutation (SNP) | VAF 20/101 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.25); catalogued as COSV62171379; called by muse, mutect2, varscan2
- CSPG4 | c.5660G>A p.G1887D | Missense Mutation (SNP) | VAF 7/9 reads (78%) | SIFT tolerated (0.67); PolyPhen benign (0.01); catalogued as rs1236812730, COSV100413783; called by muse, mutect2, varscan2
- CUBN | c.6356C>T p.S2119F | Missense Mutation (SNP) | VAF 36/56 reads (64%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.995); catalogued as COSV64714165; called by muse, mutect2, varscan2
- EFNB2 | c.848G>T p.G283V | Missense Mutation (SNP) | VAF 23/56 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV55364482; called by muse, mutect2, varscan2
- FCGBP | c.6587G>A p.R2196H | Missense Mutation (SNP) | VAF 26/213 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.987); catalogued as rs1219193234, COSV99663142; called by muse, mutect2, varscan2
- FCSK | c.2380G>A p.A794T | Missense Mutation (SNP) | VAF 26/44 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs780967695, COSV55370020; called by muse, mutect2, varscan2
- FLG | c.11414G>A p.G3805E | Missense Mutation (SNP) | VAF 80/422 reads (19%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.994); catalogued as COSV64240725; called by muse, mutect2, varscan2
- GP9 | c.62C>T p.P21L | Missense Mutation (SNP) | VAF 11/17 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV100264660; called by muse, mutect2, varscan2
- HHIPL2 | c.871A>G p.I291V | Missense Mutation (SNP) | VAF 103/207 reads (50%) | SIFT tolerated (1); PolyPhen benign (0.08); catalogued as rs994053473, COSV58564744; called by muse, mutect2, varscan2
- HTR1F | c.865C>T p.R289W | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs767724180, COSV60389492, COSV60390916; called by muse, mutect2, varscan2
- IDE | c.2930A>G p.D977G | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as COSV56422888; called by muse, mutect2, varscan2
- KBTBD12 | c.854C>A p.S285* | Nonsense Mutation (SNP) | VAF 32/70 reads (46%) | catalogued as rs1416120676, COSV100675434; called by muse, mutect2, varscan2
- KCTD18 | c.1022G>A p.G341E | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0); catalogued as COSV63344226; called by muse, mutect2, varscan2
- KLHL1 | c.1528G>C p.V510L | Missense Mutation (SNP) | VAF 56/128 reads (44%) | SIFT tolerated (0.07); PolyPhen benign (0.381); catalogued as COSV64771175; called by muse, mutect2, varscan2
- LTBP1 | c.3226C>T p.H1076Y (on ENST00000404816 / NM_206943.4; = p.H750Y on NM_000627.4) | Missense Mutation (SNP) | VAF 23/60 reads (38%) | SIFT tolerated (0.51); PolyPhen possibly damaging (0.483); catalogued as rs1558960532, COSV55378453, COSV99697639; called by muse, mutect2, varscan2
- LYZ | c.361C>T p.P121S | Missense Mutation (SNP) | VAF 24/512 reads (5%) | SIFT tolerated (0.05); PolyPhen benign (0.111); catalogued as COSV54260673; called by muse, mutect2
- MAP3K4 | c.841G>A p.D281N | Missense Mutation (SNP) | VAF 31/79 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62332715; called by muse, mutect2, varscan2
- NAALADL2 | c.1545G>T p.K515N | Missense Mutation (SNP) | VAF 3/14 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as COSV101380140; called by muse, mutect2
- NACC1 | c.308C>T p.T103M | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1391725589, COSV52834469; called by muse, mutect2, varscan2
- NFE2L2 | c.157A>C p.K53Q | Missense Mutation (SNP) | VAF 59/108 reads (55%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as COSV67960941; called by muse, mutect2, varscan2
- NUP210 | c.1460G>A p.W487* | Nonsense Mutation (SNP) | VAF 11/27 reads (41%) | catalogued as COSV99596218; called by muse, mutect2, varscan2
- OR8B3 | c.298C>G p.Q100E | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV63541386, COSV63541604; called by muse, mutect2
- PKLR | c.767G>A p.G256E | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0.388); catalogued as COSV61361021; called by muse, mutect2, varscan2
- PRAMEF7 | c.1180G>A p.E394K | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.238); catalogued as COSV58277874; called by mutect2, varscan2
- PTGR1 | c.668C>T p.S223L | Missense Mutation (SNP) | VAF 28/30 reads (93%) | SIFT deleterious (0.02); PolyPhen benign (0.035); catalogued as COSV53028505; called by muse, varscan2
- PYGO2 | c.907C>G p.P303A | Missense Mutation (SNP) | VAF 7/13 reads (54%) | SIFT tolerated (0.56); PolyPhen benign (0.052); catalogued as COSV63756892; called by muse, mutect2, varscan2
- RBM12 | c.746C>T p.P249L | Missense Mutation (SNP) | VAF 14/152 reads (9%) | SIFT deleterious (0.05); PolyPhen benign (0.014); catalogued as rs199976167, COSV58290936; called by muse, mutect2
- RHOB | c.193G>T p.D65Y | Missense Mutation (SNP) | VAF 49/95 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55356002; called by muse, mutect2, varscan2
- RIMS1 | c.4801G>A p.D1601N | Missense Mutation (SNP) | VAF 32/55 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV53452175; called by muse, mutect2, varscan2
- RNF39 | c.175G>T p.E59* | Nonsense Mutation (SNP) | VAF 21/37 reads (57%) | catalogued as COSV99748343; called by muse, mutect2, varscan2
- ST6GALNAC1 | c.36C>G p.S12R | Missense Mutation (SNP) | VAF 12/35 reads (34%) | PolyPhen benign (0); catalogued as COSV50074163; called by muse, mutect2, varscan2
- TET3 | c.5345A>G p.Y1782C | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1256830848, COSV101327834; called by muse, mutect2, varscan2
- TNRC18 | c.8854G>A p.E2952K | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs1270292355, COSV99786793; called by muse, mutect2, varscan2
- XKR4 | c.1016C>T p.A339V | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as rs765175807, COSV100534052, COSV59311838; called by muse, mutect2, varscan2
- ZFHX4 | c.8446G>A p.G2816R | Missense Mutation (SNP) | VAF 38/66 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs772365818, COSV50524021; called by muse, mutect2, varscan2
- GP2 | c.1171_1172del p.T391Lfs*4 (on ENST00000381362 / NM_001007240.3; = p.T388Lfs*4 on NM_001502.4) | Frame Shift Del (DEL) | VAF 14/70 reads (20%) | called by pindel, varscan2
- PRAMEF8 | c.1180G>A p.E394K | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.031); called by mutect2, varscan2
- ATAD2 | c.816T>C p.D272= | Silent (SNP) | VAF 6/56 reads (11%) | catalogued as rs148244463, COSV54881905; called by muse, mutect2, varscan2
- ATG2B | c.1257C>G p.L419= | Silent (SNP) | VAF 30/64 reads (47%) | catalogued as rs769459674, COSV63422824; called by muse, mutect2, varscan2
- ATP10A | c.2427C>T p.R809= | Silent (SNP) | VAF 14/69 reads (20%) | catalogued as COSV63516502; called by muse, mutect2, varscan2
- ATXN2L | c.2014C>T p.L672= | Silent (SNP) | VAF 16/54 reads (30%) | catalogued as rs756282442, COSV57369019; called by muse, mutect2, varscan2
- C12orf40 | c.1059A>G p.P353= | Silent (SNP) | VAF 13/24 reads (54%) | catalogued as COSV61131576; called by muse, mutect2, varscan2
- CNOT10 | c.51A>G p.T17= | Silent (SNP) | VAF 8/32 reads (25%) | catalogued as COSV59391609; called by muse, mutect2, varscan2
- CYP2A13 | c.1239C>T p.P413= | Silent (SNP) | VAF 36/102 reads (35%) | catalogued as COSV57837355; called by muse, mutect2, varscan2
- DNAH3 | c.12156A>G p.K4052= | Silent (SNP) | VAF 72/115 reads (63%) | catalogued as COSV54517368; called by muse, mutect2, varscan2
- FAM71C | c.360G>C p.L120= | Silent (SNP) | VAF 23/79 reads (29%) | catalogued as COSV60943078; called by muse, mutect2, varscan2
- KCTD19 | c.1074C>A p.I358= | Silent (SNP) | VAF 14/50 reads (28%) | catalogued as COSV58572426; called by muse, mutect2, varscan2
- NLRP2 | c.1407T>C p.D469= | Silent (SNP) | VAF 21/61 reads (34%) | catalogued as rs1654491; called by muse, mutect2, varscan2
- OBSCN | c.801C>T p.P267= | Silent (SNP) | VAF 7/70 reads (10%) | catalogued as rs1363028494, COSV52766639; called by muse, mutect2, varscan2
- PCDH7 | c.1695T>C p.G565= | Silent (SNP) | VAF 20/47 reads (43%) | catalogued as COSV62338270; called by muse, mutect2, varscan2
- PDE4DIP | c.1581C>T p.L527= | Silent (SNP) | VAF 70/161 reads (43%) | catalogued as rs782611853, COSV57691914; called by muse, mutect2, varscan2
- SFXN2 | c.462A>G p.T154= | Silent (SNP) | VAF 10/20 reads (50%) | catalogued as COSV64012147; called by muse, mutect2, varscan2
- SMARCA4 | c.3921C>T p.A1307= | Silent (SNP) | VAF 22/63 reads (35%) | catalogued as COSV60792152; called by muse, mutect2, varscan2
- SMC4 | c.1884A>G p.K628= | Silent (SNP) | VAF 15/96 reads (16%) | catalogued as COSV61004418; called by muse, mutect2, varscan2
- SYNJ2 | c.2064C>T p.A688= | Silent (SNP) | VAF 14/34 reads (41%) | catalogued as rs756320625, COSV62896944; called by muse, mutect2, varscan2
- YJU2 | c.6G>T p.S2= | Silent (SNP) | VAF 16/73 reads (22%) | catalogued as COSV53606010; called by muse, mutect2, varscan2
- ZNF532 | c.573G>A p.T191= | Silent (SNP) | VAF 64/108 reads (59%) | catalogued as rs371823083, COSV60172659; called by muse, mutect2, varscan2
